Somatic mutation profile of tumor specimen MP2PRT-PATHCV-TMP1-A (aliquot MP2PRT-PATHCV-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATHCV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,593 days).
Specimen MP2PRT-PATHCV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c417c12a-8723-4bdd-9d8e-d9cff0798179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHCV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHCV-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f190400-1f47-4372-85c0-49fdf69e23d4

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 111/310 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DTYMK | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 183/407 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762448283; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 236/517 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2, varscan2
- GABRA4 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 123/309 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51921853; called by muse, mutect2, varscan2
- MYCBP2 | c.11741T>C p.M3914T (on ENST00000357337; = p.M3952T on NM_015057.5) | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV62015116; called by muse, varscan2
- UMOD | c.1544C>T p.T515M | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs550521976; called by muse, mutect2, varscan2
- IGKV1-37 | chr2:89297263 GAGG>TCTGGCAC | Missense Mutation (INS) | VAF 52/337 reads (15%) | called by pindel, varscan2*
- INPP4B | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIAS1 | c.1296_1298dup p.D433dup | In Frame Ins (INS) | VAF 59/141 reads (42%) | called by mutect2, pindel, varscan2
- RNF17 | c.3347C>A p.S1116* | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | called by muse, mutect2, varscan2
- GRIK3 | c.2301C>T p.I767= | Silent (SNP) | VAF 87/200 reads (44%) | catalogued as rs766887566, COSV100901008; called by muse, mutect2, varscan2
- OR5L2 | c.348C>T p.A116= | Silent (SNP) | VAF 220/497 reads (44%) | catalogued as rs770843874, COSV65723491; called by muse, mutect2, varscan2
